Somatic mutation profile of tumor specimen MP2PRT-PAUVYV-TMP1-A (aliquot MP2PRT-PAUVYV-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUVYV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.0 years (1,461 days).
Specimen MP2PRT-PAUVYV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 737131dd-38b9-40d1-ad3e-e0c16ff11649.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVYV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVYV-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7e728e4-1b67-4d80-a666-2f0bba855840

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LGI1 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 100/478 reads (21%) | catalogued as rs886039496, COSV65057736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARSH | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 154/670 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs139674879, COSV66962789; called by muse, mutect2, varscan2
- CARD14 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 147/537 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs144570537; called by muse, mutect2, varscan2
- GGACT | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 193/512 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs934050720; called by muse, varscan2
- GRIA3 | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 163/633 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52072613; called by muse, mutect2, varscan2
- PTPRT | c.3628G>T p.D1210Y | Missense Mutation (SNP) | VAF 75/414 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100628081, COSV61998148; called by muse, mutect2, varscan2
- AKAP9 | c.5998C>G p.Q2000E (on ENST00000359028; = p.Q1968E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- KIAA0319L | c.1664G>C p.R555T | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2
- KRTAP12-4 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 143/834 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRRC4B | c.1865A>G p.D622G | Missense Mutation (SNP) | VAF 256/662 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- UBN2 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- IFIT5 | c.483G>T p.A161= | Silent (SNP) | VAF 38/662 reads (6%) | catalogued as rs147024608; called by muse, mutect2
- IGHV1-45 | chr14:106506995 ins C | 3'Flank (INS) | VAF 34/98 reads (35%) | called by mutect2, pindel*, varscan2
